Somatic mutation profile of tumor specimen TCGA-EJ-A65D-01A (aliquot TCGA-EJ-A65D-01A-11D-A30E-08) from TCGA case TCGA-EJ-A65D, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,297 days).
Specimen TCGA-EJ-A65D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbf8f613-2481-4b31-a6e3-9237ffa75f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A65D-10A (Blood Derived Normal), aliquot TCGA-EJ-A65D-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ab0ce3b-a282-4ae1-9a6f-1c96a0eaff26

The open-access MAF lists 30 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 3, Intron 1, Frame Shift Ins 1, Nonstop Mutation 1, Frame Shift Del 1, Nonsense Mutation 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 54/114 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1433282186, COSV53933309, COSV99654063; called by muse, mutect2, varscan2
- CACNA1F | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782005253, COSV59904055; called by muse, mutect2
- CCDC39 | c.1675A>T p.I559L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV56496328; called by muse, mutect2, varscan2
- CD163L1 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 64/125 reads (51%) | catalogued as rs766981681, COSV58018107; called by muse, mutect2, varscan2
- DHTKD1 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759029764, COSV53808473; called by muse, mutect2, varscan2
- DLGAP1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs113585667, COSV100232973, COSV59845252; called by muse, mutect2, varscan2
- INPP5J | c.2698C>T p.R900W (on ENST00000331075 / NM_001284285.2; = p.R532W on NM_001002837.2) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs1257966503, COSV53213336; called by muse, mutect2, varscan2
- KREMEN2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/98 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV53557722; called by muse, mutect2, varscan2
- NTRK1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV62329182; called by muse, mutect2, varscan2
- OR2T3 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100613293; called by muse, mutect2, varscan2
- PCDH15 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs370933593, COSV57261997; called by muse, mutect2, varscan2
- PCDHB6 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 93/170 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50692259; called by muse, mutect2, varscan2
- PRKG1 | c.265del p.Q89Rfs*6 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as COSV64830812; called by mutect2, pindel, varscan2
- PROS1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758232970, CM971241, COSV62399941; called by muse, mutect2, varscan2
- PSPC1 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58891575; called by muse, mutect2
- SIM1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV53498076; called by muse, mutect2, varscan2
- STXBP5L | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56541038; called by muse, mutect2, varscan2
- TNFRSF13B | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1430117089, COSV55428688, COSV55430832; called by muse, mutect2, varscan2
- TOE1 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV59158496; called by muse, mutect2, varscan2
- UNC13C | c.5457G>A p.E1819= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as COSV52935227; called by muse, mutect2, varscan2
- ZC3H10 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV57770262; called by muse, mutect2, varscan2
- ACACA | c.6389G>T p.W2130L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASZ1 | c.2153_2162dup p.S721Rfs*10 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | called by mutect2, varscan2
- PIK3CA | c.3207_*10del | Nonstop Mutation (DEL) | VAF 33/82 reads (40%) | called by mutect2, pindel, varscan2
- HNRNPCL1 | c.315C>T p.Y105= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as rs765628936, COSV58609803; called by muse, mutect2, varscan2
- PCLO | c.13167G>A p.R4389= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs1031092478, COSV100426555, COSV61677226; called by muse, mutect2, varscan2
- WDR72 | c.2985G>A p.A995= | Silent (SNP) | VAF 77/190 reads (41%) | catalogued as rs745403939, COSV64745745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CA6 | c.259+2213C>T | Intron (SNP) | VAF 20/49 reads (41%) | catalogued as rs754485409, COSV66263290; called by muse, mutect2
